Somatic mutation profile of tumor specimen TCGA-DK-AA6Q-01A (aliquot TCGA-DK-AA6Q-01A-11D-A391-08) from TCGA case TCGA-DK-AA6Q, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 61.1 years (22,314 days).
Specimen TCGA-DK-AA6Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) eec468bd-8a55-4f06-8ea4-4be4f241d24d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DK-AA6Q-10A (Blood Derived Normal), aliquot TCGA-DK-AA6Q-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2af4b6df-a259-41af-8e52-e5dde51d7af5

The open-access MAF lists 128 somatic variants for this specimen: 104 protein-altering or splice-affecting, 22 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 90, Silent 22, Nonsense Mutation 6, Frame Shift Del 3, In Frame Del 2, Splice Site 2, Splice Region 1, RNA 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.100C>G p.R34G | Missense Mutation (SNP) | VAF 43/72 reads (60%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67960061, COSV67960966; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 46/66 reads (70%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 19/37 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACSF3 | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs774006659, COSV100441008; called by muse, mutect2, varscan2
- AHCYL2 | c.854C>T p.S285L | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV100272776; called by muse, varscan2
- ANO9 | c.2148C>G p.I716M | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV100229752; called by muse, mutect2, varscan2
- ARFGEF3 | c.1978C>G p.L660V | Missense Mutation (SNP) | VAF 22/40 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as COSV52449645; called by muse, mutect2, varscan2
- ATG2B | c.4231G>A p.D1411N | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV55890261; called by muse, mutect2, varscan2
- BACH1 | c.2020G>A p.D674N | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV54521219, COSV99727849; called by muse, mutect2
- CDH1 | c.1768G>A p.D590N | Missense Mutation (SNP) | VAF 40/112 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); catalogued as COSV99931059; called by muse, mutect2, varscan2
- CDHR1 | c.1675G>A p.V559I | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.081); catalogued as rs778340853, COSV60565934; called by muse, mutect2
- CNTNAP4 | c.2710G>A p.A904T | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0.007); catalogued as rs376248782, COSV100268994, COSV56698683; called by muse, mutect2, varscan2
- COL4A4 | c.845G>A p.G282E | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61633842; called by muse, mutect2, varscan2
- CPLANE1 | c.8681G>T p.R2894I | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV57058027, COSV99949320; called by muse, mutect2, varscan2
- DDX3X | c.982G>C p.D328H (on ENST00000399959; = p.D329H on NM_001356.5) | Missense Mutation (SNP) | VAF 68/157 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101302320, COSV101302559; called by muse, mutect2, varscan2
- DENND5A | c.1718C>G p.S573* | Nonsense Mutation (SNP) | VAF 14/55 reads (25%) | catalogued as COSV100063882; called by muse, mutect2, varscan2
- DPH2 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV52542737, COSV99356213; called by muse, mutect2, varscan2
- DYRK3 | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100895561; called by muse, mutect2, varscan2
- EHBP1L1 | c.2143G>A p.E715K | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.643); catalogued as COSV100499582; called by muse, mutect2, varscan2
- EHBP1L1 | c.3133G>C p.E1045Q | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.311); catalogued as rs1247603493, COSV100499585; called by muse, mutect2, varscan2
- EHD2 | c.1463G>A p.R488H | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.052); catalogued as COSV54408047; called by muse, mutect2, varscan2
- EPS15 | c.2488G>A p.A830T | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs1200883568, COSV100869384; called by muse, mutect2, varscan2
- FAF2 | c.197C>T p.S66L | Missense Mutation (SNP) | VAF 27/48 reads (56%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV99990170; called by muse, mutect2, varscan2
- FBXW2 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT tolerated (0.86); PolyPhen benign (0.003); catalogued as COSV100535045; called by muse, varscan2
- FBXW2 | c.6G>C p.E2D | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.003); catalogued as COSV100535048; called by muse, varscan2
- FREM1 | c.3489G>A p.M1163I | Missense Mutation (SNP) | VAF 39/65 reads (60%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as COSV101083609; called by muse, mutect2, varscan2
- FSHR | c.1843C>T p.H615Y | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58621594; called by muse, mutect2, varscan2
- GPR101 | c.437G>A p.R146H | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.25); PolyPhen benign (0.025); catalogued as COSV53240549; called by muse, mutect2, varscan2
- GPR108 | c.1560-1G>T p.X520_splice (on ENST00000264080 / NM_001080452.1; = p.X278_splice on NM_020171.2) | Splice Site (SNP) | VAF 17/46 reads (37%) | catalogued as COSV99901101; called by muse, mutect2, varscan2
- H2BC7 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.014); catalogued as COSV61911735, COSV61912284; called by muse, mutect2, varscan2
- HEPH | c.1620C>G p.F540L (on ENST00000343002; = p.F273L on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as COSV100293947; called by muse, mutect2, varscan2
- HIVEP3 | c.3355G>A p.E1119K | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.98); catalogued as rs1381432863, COSV99911195, COSV99913221; called by muse, mutect2, varscan2
- HTR3D | c.956G>A p.G319D (on ENST00000382489 / NM_001163646.2; = p.G144D on NM_182537.3) | Missense Mutation (SNP) | VAF 78/118 reads (66%) | SIFT tolerated (0.05); PolyPhen benign (0.425); catalogued as COSV100487829; called by muse, mutect2, varscan2
- IFNGR2 | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM131737, COSV99274494; called by muse, mutect2, varscan2
- INTS6L | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV100877999; called by muse, mutect2, varscan2
- IRAG2 | c.3902C>A p.S1301* (on ENST00000636465; = p.S346* on NM_006152.4 and 7 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 10/56 reads (18%) | catalogued as COSV100208784; called by muse, mutect2, varscan2
- KITLG | c.775G>C p.E259Q | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as COSV99933056; called by muse, mutect2, varscan2
- LIPG | c.607G>A p.D203N | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.936); catalogued as rs368016590; called by muse, mutect2, varscan2
- MAP2 | c.1598T>G p.I533S | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.009); catalogued as COSV99557384; called by muse, mutect2, varscan2
- MAP3K9 | c.2263G>A p.G755S (on ENST00000554752 / NM_001284230.1; = p.G769S on NM_033141.4) | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.956); catalogued as rs999475384, COSV101173424; called by muse, mutect2, varscan2
- MEGF10 | c.3010G>A p.G1004R | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs1334309647, COSV99174667; called by muse, mutect2, varscan2
- MTARC2 | c.425C>T p.S142L | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.405); catalogued as rs777213689, COSV100830837; called by muse, mutect2, varscan2
- MUC16 | c.29429C>G p.S9810* | Nonsense Mutation (SNP) | VAF 26/50 reads (52%) | catalogued as COSV101197495; called by muse, mutect2, varscan2
- MYO5C | c.3773G>A p.G1258E | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT tolerated (0.69); PolyPhen benign (0.024); catalogued as rs754432972, COSV99953919; called by muse, mutect2, varscan2
- MYT1 | c.1379A>G p.H460R | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100113806; called by muse, mutect2, varscan2
- NFE2L3 | c.1042C>T p.H348Y | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV50226242, COSV99283412; called by muse, mutect2, varscan2
- NMT1 | c.1475G>C p.G492A | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.255); catalogued as COSV99364524; called by muse, mutect2, varscan2
- NUP188 | c.1933C>G p.P645A | Missense Mutation (SNP) | VAF 24/47 reads (51%) | SIFT tolerated (0.75); PolyPhen benign (0.112); catalogued as COSV101001131; called by muse, mutect2, varscan2
- OR10V1 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.968); catalogued as COSV100275482; called by muse, mutect2, varscan2
- PAPPA2 | c.446G>T p.G149V | Missense Mutation (SNP) | VAF 11/112 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.211); catalogued as COSV100866459, COSV62785917; called by muse, mutect2
- PCARE | c.2126G>C p.G709A | Missense Mutation (SNP) | VAF 48/109 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.037); catalogued as COSV100527233, COSV59059476; called by muse, mutect2, varscan2
- PCDHB13 | c.1050G>A p.M350I | Missense Mutation (SNP) | VAF 76/127 reads (60%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.005); catalogued as rs1554287810, COSV99506568, COSV99507348; called by muse, mutect2, varscan2
- PCLO | c.5321C>T p.S1774L | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61616208; called by muse, mutect2, varscan2
- PCNX4 | c.2849C>T p.S950L (on ENST00000406854 / NM_001330177.2; = p.S716L on NM_022495.5) | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs368524303, COSV100469711; called by muse, mutect2, varscan2
- PIK3C2G | c.4063G>T p.E1355* (on ENST00000676171; = p.E1314* on NM_004570.5) | Nonsense Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as COSV56807745, COSV56823386, COSV99848869; called by muse, mutect2, varscan2
- PLCB4 | c.3477G>C p.Q1159H (on ENST00000278655 / NM_182797.3; = p.D1172H on NM_000933.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV53804604, COSV99593910; called by muse, mutect2, varscan2
- PLEKHH1 | c.226C>G p.L76V | Missense Mutation (SNP) | VAF 9/17 reads (53%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as COSV100232540, COSV61282592; called by muse, mutect2, varscan2
- POLR1A | c.4216G>C p.E1406Q | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.16); catalogued as COSV55691748, COSV99807004; called by muse, mutect2
- PRICKLE1 | c.2011C>G p.H671D | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as COSV100453357; called by muse, mutect2, varscan2
- PRKG1 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV100907624, COSV100908012; called by muse, mutect2, varscan2
- PROM1 | c.878G>C p.S293T | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.484); catalogued as COSV101477029; called by muse, mutect2, varscan2
- PTPRT | c.2313-1G>T p.X771_splice | Splice Site (SNP) | VAF 21/73 reads (29%) | catalogued as COSV100628668, COSV62010035; called by muse, mutect2, varscan2
- RAB38 | c.78C>G p.I26M | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54712589, COSV54717115; called by muse, mutect2, varscan2
- RNF141 | c.22C>G p.Q8E | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.04); catalogued as COSV56416338; called by muse, mutect2, varscan2
- RNF19B | c.1641G>C p.K547N | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV52388528, COSV99331113; called by muse, mutect2, varscan2
- RNF2 | c.641T>A p.M214K | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV100835634; called by muse, mutect2, varscan2
- RNF31 | c.1036G>C p.E346Q | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.068); catalogued as COSV53760736, COSV99395850; called by muse, mutect2, varscan2
- RP9 | c.500C>G p.S167C | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.865); catalogued as COSV99777887; called by muse, mutect2, varscan2
- RPS9 | c.479C>T p.S160F | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.019); catalogued as rs11544023, COSV100256317; called by muse, mutect2, varscan2
- SCN3A | c.4363G>A p.G1455R | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51806056, COSV99325443; called by muse, mutect2, varscan2
- SEC14L4 | c.1196C>T p.A399V | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.052); catalogued as rs148376799, COSV99742560; called by muse, mutect2, varscan2
- SEMA3E | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1325245021, COSV100316956; called by muse, mutect2, varscan2
- SERPINB13 | c.745C>A p.P249T | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1399269302, COSV99500790; called by muse, mutect2, varscan2
- SLC23A2 | c.933C>G p.F311L | Missense Mutation (SNP) | VAF 39/116 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100594722; called by muse, mutect2, varscan2
- SLC41A1 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as COSV100900307; called by muse, mutect2, varscan2
- SMG5 | c.1548G>A p.M516I | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.1); catalogued as COSV100700676; called by muse, mutect2, varscan2
- SNED1 | c.902C>G p.S301W | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1159962124, COSV60033246, COSV60034385; called by muse, mutect2
- SPTBN1 | c.2755G>C p.G919R | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.261); catalogued as COSV100441537; called by muse, mutect2, varscan2
- SSPOP | n.7210T>C | Splice Region (SNP) | VAF 17/41 reads (41%) | catalogued as rs1331148306, COSV100022043; called by muse, mutect2, varscan2
- TAS2R30 | c.123C>G p.I41M | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.771); catalogued as COSV101113928; called by muse, mutect2, varscan2
- TENM4 | c.2917C>T p.R973W | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.549); catalogued as rs201737432, COSV53648435; called by muse, mutect2, varscan2
- TENT4B | c.1703G>A p.R568K (on ENST00000561678 / NM_001365323.2; = p.R553K on NM_001040284.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV62546074; called by muse, mutect2, varscan2
- TRAF3IP2 | c.874C>T p.R292* | Nonsense Mutation (SNP) | VAF 22/38 reads (58%) | catalogued as rs774729962, COSV100389577; called by muse, mutect2, varscan2
- TRANK1 | c.4862C>T p.S1621F | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.651); catalogued as COSV100081056; called by muse, mutect2, varscan2
- TTC27 | c.1777G>A p.D593N | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs200122950; called by muse, mutect2, varscan2
- TTLL3 | c.2690G>C p.G897A | Missense Mutation (SNP) | VAF 34/68 reads (50%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as COSV100047083; called by muse, mutect2, varscan2
- TTN | c.71107C>T p.R23703W (on ENST00000591111; = p.R16279W on NM_003319.4) | Missense Mutation (SNP) | VAF 24/68 reads (35%) | PolyPhen probably damaging (0.96); catalogued as rs371696090; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TYK2 | c.723C>A p.F241L | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs761425610, COSV99314059; called by muse, mutect2, varscan2
- USP13 | c.1594C>T p.P532S | Missense Mutation (SNP) | VAF 54/83 reads (65%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.837); catalogued as COSV99830636, COSV99831930; called by muse, mutect2, varscan2
- USP29 | c.340G>T p.D114Y | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.809); catalogued as COSV99571615; called by muse, mutect2, varscan2
- ZBED4 | c.1679C>T p.T560I | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.421); catalogued as COSV99350700; called by muse, mutect2, varscan2
- ZC3H6 | c.2687C>G p.S896C | Missense Mutation (SNP) | VAF 13/30 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100674303; called by muse, mutect2, varscan2
- ZC3H6 | c.2867C>A p.S956* | Nonsense Mutation (SNP) | VAF 24/70 reads (34%) | catalogued as COSV59665900; called by muse, mutect2, varscan2
- ZFP42 | c.689C>T p.S230L | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.458); catalogued as COSV58817432, COSV58817459, COSV58818701; called by muse, mutect2, varscan2
- ZIM3 | c.915A>C p.K305N | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99517526; called by muse, mutect2, varscan2
- ZNF630 | c.75G>C p.L25F | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99332170; called by muse, mutect2, varscan2
- CDKN2A | c.300_310del p.A102Rfs*14 | Frame Shift Del (DEL) | VAF 6/15 reads (40%) | called by mutect2, varscan2
- DLX3 | c.246del p.K83Sfs*29 | Frame Shift Del (DEL) | VAF 14/68 reads (21%) | called by mutect2, pindel, varscan2
- IGLV1-50 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 15/110 reads (14%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- IKBKB | c.820_822del p.E274del | In Frame Del (DEL) | VAF 8/30 reads (27%) | called by mutect2, pindel, varscan2
- PTPRS | c.4459A>T p.I1487F | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); called by muse, mutect2
- RTL9 | c.1787_1788del p.T596Sfs*42 | Frame Shift Del (DEL) | VAF 18/72 reads (25%) | called by pindel, varscan2
- SCN3A | c.4652G>T p.G1551V | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.038); called by muse, mutect2
- TAF6L | c.471_473del p.L158del | In Frame Del (DEL) | VAF 10/87 reads (11%) | called by mutect2, pindel, varscan2
- ABCA10 | c.1113G>A p.E371= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as COSV52227260, COSV99287671; called by muse, mutect2, varscan2
- DDX47 | c.1197G>C p.L399= | Silent (SNP) | VAF 43/128 reads (34%) | catalogued as COSV100774465; called by muse, mutect2, varscan2
- DDX49 | c.690C>T p.V230= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV99447056; called by muse, mutect2, varscan2
- GAPDHS | c.486G>C p.G162= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as COSV99722181; called by mutect2, varscan2
- GKAP1 | c.273C>T p.N91= | Silent (SNP) | VAF 5/99 reads (5%) | catalogued as rs1405545766, COSV100897569; called by muse, mutect2
- GTPBP6 | c.909C>T p.T303= | Silent (SNP) | VAF 16/38 reads (42%) | catalogued as COSV100397585; called by muse, mutect2, varscan2
- HHAT | c.57C>T p.F19= | Silent (SNP) | VAF 15/56 reads (27%) | catalogued as rs767538110, COSV99802121; called by muse, mutect2, varscan2
- MB21D2 | c.909C>T p.S303= | Silent (SNP) | VAF 40/68 reads (59%) | catalogued as COSV101164974; called by muse, mutect2, varscan2
- MFSD3 | c.873C>T p.L291= | Silent (SNP) | VAF 37/115 reads (32%) | catalogued as rs752996137, COSV56740559; called by muse, mutect2, varscan2
- MKRN3 | c.300C>A p.I100= | Silent (SNP) | VAF 30/65 reads (46%) | catalogued as COSV100090566; called by muse, mutect2, varscan2
- MYO5C | c.3774A>T p.G1258= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as COSV99953917; called by muse, mutect2, varscan2
- NBEAL1 | c.4089C>T p.F1363= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV101495592; called by muse, mutect2, varscan2
- PHF10 | c.829C>T p.L277= | Silent (SNP) | VAF 12/25 reads (48%) | catalogued as COSV100199675; called by muse, mutect2
- PTPRB | c.4761C>G p.L1587= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs1161917907, COSV99715400; called by muse, mutect2, varscan2
- RAG1 | c.99C>T p.F33= | Silent (SNP) | VAF 17/59 reads (29%) | catalogued as COSV55027376; called by muse, mutect2, varscan2
- RANBP6 | c.1968G>T p.V656= | Silent (SNP) | VAF 42/75 reads (56%) | catalogued as COSV99423904; called by muse, mutect2, varscan2
- SERPINA12 | c.867G>A p.V289= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as COSV100369540; called by muse, mutect2, varscan2
- SERPINB5 | c.576C>T p.T192= | Silent (SNP) | VAF 17/91 reads (19%) | catalogued as COSV101237570; called by muse, mutect2, varscan2
- SLC35F1 | c.591C>T p.G197= | Silent (SNP) | VAF 53/125 reads (42%) | catalogued as COSV100837388, COSV64498935; called by muse, mutect2, varscan2
- SURF6 | c.441G>A p.R147= | Silent (SNP) | VAF 53/161 reads (33%) | catalogued as COSV100921108; called by muse, mutect2, varscan2
- TAS1R2 | c.1230C>T p.C410= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV100946115, COSV100946279; called by muse, mutect2
- TTF1 | c.186C>T p.L62= | Silent (SNP) | VAF 31/95 reads (33%) | catalogued as COSV100524414, COSV57504073; called by muse, mutect2, varscan2
- PSD3 | c.2176-28114C>G | Intron (SNP) | VAF 34/111 reads (31%) | catalogued as COSV54084010; called by muse, mutect2, varscan2
- SSPOP | n.7211C>A | RNA (SNP) | VAF 18/41 reads (44%) | catalogued as COSV100022044, COSV50487607; called by muse, mutect2, varscan2
